Somatic mutation profile of tumor specimen TCGA-VD-AA8S-01B (aliquot TCGA-VD-AA8S-01B-11D-A39W-08) from TCGA case TCGA-VD-AA8S, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 40.2 years (14,681 days).
Specimen TCGA-VD-AA8S-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e187151c-62d1-4f5f-8006-80e724992fac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8S-10A (Blood Derived Normal), aliquot TCGA-VD-AA8S-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21ea7e21-62d0-4e2d-bb27-7e930603bcca

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 51/80 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.3398G>A p.W1133* (on ENST00000354582; = p.W1118* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as COSV56970516; called by muse, mutect2, varscan2
- KCNK13 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs538269862; called by muse, mutect2, varscan2
- COA7 | c.418del p.R140Gfs*37 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- MACF1 | c.14584G>A p.G4862R (on ENST00000372915; = p.G2795R on NM_012090.5) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- SERPINA9 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
